Somatic mutation profile of tumor specimen TCGA-41-2571-01A (aliquot TCGA-41-2571-01A-01D-1495-08) from TCGA case TCGA-41-2571, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 89.3 years (32,612 days).
Specimen TCGA-41-2571-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f38fd65b-4d7b-4ecc-9957-459470d33a79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-2571-10A (Blood Derived Normal), aliquot TCGA-41-2571-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/178c6e9c-d5d9-42fb-b91a-ac6f83acafaa

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Nonsense Mutation 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 73/106 reads (69%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- APOBR | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as COSV60493036; called by muse, mutect2, varscan2
- ARMC6 | c.1063G>T p.A355S (on ENST00000392336; = p.A330S on NM_033415.4) | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.624); catalogued as COSV54183468; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CCR4 | c.974T>A p.L325H | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.078); catalogued as COSV58383388; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CD96 | c.1493G>A p.G498E (on ENST00000283285 / NM_198196.3; = p.G482E on NM_005816.5) | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV51920536; called by muse, mutect2, varscan2
- CRYGD | c.450C>G p.D150E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52205851; called by muse, mutect2, varscan2
- DST | c.19787G>C p.R6596T (on ENST00000361203 / NM_001374722.1; = p.R4293T on NM_015548.5) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55032499, COSV55039814; called by muse, mutect2, varscan2
- DUS3L | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57833107; called by muse, mutect2, varscan2
- EIF3M | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as rs1295445179, COSV60072449; called by muse, mutect2, varscan2
- EMC1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.379); catalogued as COSV64346362; called by muse, mutect2
- FAM118A | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs140683394, COSV99343730; called by muse, mutect2, varscan2
- GPR142 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as rs371610556; called by muse, mutect2, varscan2
- HPS3 | c.322A>C p.M108L | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56056589; called by muse, mutect2, varscan2
- JAG1 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as COSV54761118; called by muse, mutect2, varscan2
- JAKMIP3 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as rs372190425; called by muse, varscan2
- KANK1 | c.3035G>T p.S1012I | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63214316; called by muse, mutect2, varscan2
- LY9 | c.1721A>G p.D574G | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs765047414, COSV54436526; called by muse, mutect2, varscan2
- MNT | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1385965251, COSV51513510; called by muse, mutect2
- PCDHGA7 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.025); catalogued as rs1012277194, COSV54004726; called by muse, mutect2, varscan2
- PLA2G2F | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.6); catalogued as rs750448231, COSV64280232, COSV64280263; called by muse, mutect2, varscan2
- PPA2 | c.848G>A p.C283Y (on ENST00000341695 / NM_176869.3; = p.C254Y on NM_006903.4) | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV58997541; called by muse, mutect2, varscan2
- PPP1R3A | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs868174796, COSV52875758; called by muse, mutect2, varscan2
- PSG8 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs200167716, COSV100126217; called by muse, mutect2, varscan2
- SLC28A1 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV54483432; called by muse, mutect2, varscan2
- SMR3B | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100513428; called by muse, mutect2, varscan2
- SPTA1 | c.2860A>T p.S954C | Missense Mutation (SNP) | VAF 112/360 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63757469; called by muse, mutect2
- TBP | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57832620, COSV57833387; called by muse, mutect2, varscan2
- TBXAS1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs779684101, COSV54951358; called by muse, mutect2, varscan2
- TLR1 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 71/194 reads (37%) | catalogued as COSV58305218; called by muse, mutect2, varscan2
- VWF | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.579); catalogued as CM092251, COSV54630058; called by muse, mutect2, varscan2
- GSE1 | c.3258del p.T1087Lfs*51 | Frame Shift Del (DEL) | VAF 48/147 reads (33%) | called by mutect2, pindel, varscan2
- ABR | c.2145C>T p.N715= (on ENST00000302538 / NM_021962.5; = p.N678= on NM_001092.5) | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs757193320, COSV52149901; called by muse, mutect2, varscan2
- ALDOA | c.951C>T p.P317= (on ENST00000642816 / NM_001243177.4; = p.P263= on NM_184041.5) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs747443135, COSV57633581; called by muse, mutect2, varscan2
- CALHM2 | c.252C>T p.A84= | Silent (SNP) | VAF 52/84 reads (62%) | catalogued as rs200157737, COSV53297373; called by muse, mutect2, varscan2
- CEP350 | c.1065G>A p.V355= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV62607907; called by muse, mutect2, varscan2
- CEP57L1 | c.1074C>T p.D358= | Silent (SNP) | VAF 58/105 reads (55%) | catalogued as rs767040592, COSV61245928; called by muse, mutect2, varscan2
- COL19A1 | c.2538T>A p.P846= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV59582464; called by muse, mutect2, varscan2
- COL1A1 | c.2283C>A p.G761= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs759665341, COSV56802684, COSV56808314; called by muse, mutect2, varscan2
- DRICH1 | c.6G>A p.G2= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV58504535; called by muse, mutect2
- ELK3 | c.570C>T p.T190= | Silent (SNP) | VAF 59/161 reads (37%) | catalogued as rs369779294; called by muse, mutect2, varscan2
- HLA-E | c.627C>T p.H209= | Silent (SNP) | VAF 90/230 reads (39%) | catalogued as rs774785851, COSV64927782; called by muse, mutect2, varscan2
- MACROD2 | c.441A>T p.P147= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV54029289; called by muse, mutect2
- OR2T12 | c.962G>A p.*321= | Silent (SNP) | VAF 84/318 reads (26%) | catalogued as rs866792488, COSV58776610; called by muse, mutect2, varscan2
- PIWIL4 | c.1476C>T p.S492= | Silent (SNP) | VAF 103/300 reads (34%) | catalogued as rs775511179, COSV54407667; called by muse, mutect2
- RSPH6A | c.1236C>T p.P412= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs773950083, COSV55574742; called by muse, mutect2, varscan2
- SIX5 | c.2097C>T p.P699= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs140206626; called by muse, mutect2, varscan2
- SLC14A2 | c.225C>T p.D75= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs752273819, COSV54906651; called by muse, mutect2, varscan2
- C7orf65 | n.416G>T | RNA (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
